CCDI case PBBSNL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/34d2052a-9c08-431e-bfe8-8e943ee68424

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,799 days).

Biospecimens (3 samples)
- Sample 0DFRU2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFRU3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFRU4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
